Somatic mutation profile of tumor specimen TCGA-B5-A11P-01B (aliquot TCGA-B5-A11P-01B-11D-A14G-09) from TCGA case TCGA-B5-A11P, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-B5-A11P-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e767c294-c4a1-4c40-9bdc-35eb710efad4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11P-10A (Blood Derived Normal), aliquot TCGA-B5-A11P-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80a98d6a-c3b3-4fab-af06-1c28592c48ac

The open-access MAF lists 51 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 30, Silent 13, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 14/58 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 36/111 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALG13 | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV99321778; called by muse, mutect2, varscan2
- ALPG | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs777723971, COSV99779200; called by muse, mutect2, varscan2
- AMFR | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | catalogued as rs1242357060, COSV99315672; called by muse, mutect2, varscan2
- ANK2 | c.9328G>T p.E3110* | Nonsense Mutation (SNP) | VAF 13/23 reads (57%) | catalogued as COSV100000152; called by muse, mutect2, varscan2
- AVPR1A | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.075); catalogued as COSV54547949; called by muse, mutect2, varscan2
- CHRNA2 | c.1587C>G p.I529M | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.845); catalogued as COSV99531939; called by muse, mutect2, varscan2
- COL6A2 | c.2810G>A p.R937Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs777354703, COSV99384728; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL3 | c.264+1G>A p.X88_splice | Splice Site (SNP) | VAF 34/56 reads (61%) | catalogued as COSV100023866; called by muse, mutect2, varscan2
- DHRS12 | c.517G>A p.V173I (on ENST00000444610 / NM_001377930.1; = p.V124I on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as rs145669707; called by muse, mutect2, varscan2
- FGF19 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.548); catalogued as COSV99594280; called by muse, mutect2, varscan2
- FLNA | c.5236C>A p.P1746T (on ENST00000369850 / NM_001110556.2; = p.P1738T on NM_001456.3) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100774346; called by muse, mutect2, varscan2
- GLRA3 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); catalogued as rs138454135; called by muse, mutect2, varscan2
- GPR158 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs750512446, COSV100894205, COSV66268967, COSV66282379; called by muse, mutect2, varscan2
- KCNA4 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs768852661, COSV60251924, COSV60255631; called by muse, mutect2, varscan2
- MGAT4A | c.188A>C p.N63T | Missense Mutation (SNP) | VAF 53/75 reads (71%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as COSV99384008; called by muse, mutect2, varscan2
- MTX3 | c.226C>G p.Q76E | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as COSV101560471; called by muse, mutect2, varscan2
- MZF1 | c.862C>T p.L288F | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as COSV99285077; called by muse, mutect2, varscan2
- OCRL | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as COSV100843355; called by muse, mutect2
- OR4A16 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.023); catalogued as COSV100125057; called by muse, mutect2, varscan2
- OR4C46 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.558); catalogued as rs745680497, COSV60221491; called by muse, mutect2, varscan2
- OR4C6 | c.310T>C p.F104L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.079); catalogued as COSV100051447; called by muse, varscan2
- OR52N5 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 15/15 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs368556660; called by muse, mutect2, varscan2
- P2RX3 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs759050633, COSV54441845; called by muse, mutect2, varscan2
- PLRG1 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.13); catalogued as COSV100122997; called by muse, mutect2, varscan2
- PRPF8 | c.4673C>T p.T1558M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs763913212, COSV100517219; called by muse, mutect2, varscan2
- RD3 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs369960606, COSV65363031; called by muse, mutect2, varscan2
- RSPH10B | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as COSV100521227; called by mutect2, varscan2
- RSPH10B2 | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as rs1175261702, COSV99785991; called by mutect2, varscan2
- SCO1 | c.11T>A p.L4Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.083); catalogued as COSV99703492; called by muse, mutect2, varscan2
- SLX4IP | c.755G>A p.S252N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV100570234; called by muse, mutect2, varscan2
- SRSF8 | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV101475787; called by muse, mutect2, varscan2
- TSPAN2 | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs1311025113, COSV101049833; called by muse, mutect2, varscan2
- ATP8B2 | c.898_905del p.T300Rfs*45 (on ENST00000672630; = p.T267Rfs*45 on NM_001005855.2) | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | called by mutect2, pindel, varscan2
- CREBBP | c.5301del p.R1768Afs*3 | Frame Shift Del (DEL) | VAF 15/30 reads (50%) | called by mutect2, pindel*, varscan2*
- SEMA5B | c.427del p.R143Gfs*47 | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | called by mutect2, pindel, varscan2
- TMED7 | c.526_544del p.R176* | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- ADAM29 | c.1308T>C p.T436= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs1231591947, COSV100821926; called by muse, mutect2, varscan2
- BIRC5 | c.243G>C p.S81= | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as COSV56957351; called by muse, mutect2, varscan2
- C9orf135 | c.93C>T p.G31= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV101019735; called by muse, mutect2, varscan2
- CLC | c.228G>A p.V76= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV99695550; called by muse, mutect2, varscan2
- DDX53 | c.1737C>T p.A579= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs908289733, COSV100028713; called by muse, mutect2, varscan2
- GLYATL2 | c.777T>C p.H259= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV99780242; called by muse, varscan2
- GOLM1 | c.48C>G p.L16= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV57416050, COSV99974246; called by muse, mutect2, varscan2
- MUC5B | c.10743G>A p.L3581= | Silent (SNP) | VAF 44/92 reads (48%) | catalogued as COSV101500076; called by muse, mutect2, varscan2
- OR4C6 | c.363C>T p.Y121= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as rs141756140; called by muse, varscan2
- PGAP6 | c.1152C>T p.S384= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs773052871, COSV51740085; called by muse, mutect2, varscan2
- PTPRG | c.3129G>A p.R1043= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV55654251; called by muse, mutect2, varscan2
- SSPN | c.558C>T p.S186= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as rs112964234, COSV54381028; called by muse, mutect2, varscan2
- ST13 | c.462G>A p.R154= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as rs759194262, COSV99344016; called by muse, mutect2, varscan2
